Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-B0BO, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-B0BO-TTM1-A (FFPE Scrolls).

[page 1 of 19]
Results

PATHOLOGY REPORT

PATHOLOGY REPORT

Status: Final result Visible to patient: This result is not viewable by the patient. Next appt:
In Surgical Oncology

Result Narrative

DEPARTMENT OF PATHOLOGY
SURGICAL PATHOLOGY REPORT

PATH REPORT

SEX: M

AGE:

LOC:

COLL:

HOSP#

+624

CLINICIAN:
ACC. DATE:
REPORTS TO:

+624

PATHOLOGIC DIAGNOSIS:

A. LEFT DEEP CERVICAL LYMPH NODE, BIOPSY:
-METASTATIC ADENOCARCINOMA.

B. LEFT DEEP CERVICAL LYMPH NODES #2, BIOPSY:
-METASTATIC ADENOCARCINOMA.

CLINICAL INFORMATION:

Positive bile duct tumor. Rule out metastases in node.

GROSS DESCRIPTION:

A. The specimen is received fresh for frozen section, labeled with the patient's name and designated "left deep cervical lymph node." The specimen consists of two fragments of tan-pink soft tissue ranging from 1-1.2 cm. One piece is bisected and frozen in AFS1 cryoblock. The remainder of the specimen is submitted in block A1.

B. The specimen is received in formalin, labeled with the patient's name and designated "#2 left deep cervical lymph node." The specimen consists of a tan-pink and fatty nodular tissue fragment measuring 1.8 x 1.5 x 1 cm. The node is trisected to reveal a tan-pink tumorous cut surface. The node is entirely submitted in cassettes B1 through B3.

FROZEN SECTION DIAGNOSIS:

Cervical lymph node, biopsy: Metastatic carcinoma.

Frozen section diagnosis per

MICROSCOPIC DESCRIPTION:

[page 2 of 19]
Performed.
(SIGNATURE ON FILE)

+625

+623 Specimen Collected: Last Resulted

[Order Details](#) [View Encounter](#) [Lab and Collection](#)
[Details](#) [Routing](#) [Result History](#)

Encounter

[View Encounter](#)

Result Information

Status

Final result (+625

Provider Status: Ordered

Lab Information

HLAB

Additional Information

Specimen ID

Bill Type

Client ID

Specimen Date
Taken

Specimen Time
Taken

Specimen
Received Date

Specimen
Received Time

Result Date

Result Time

+623 **PATHOLOGY REPORT** (Order +624 +625

Lab

Released By: Auto-released

Date

Order:

Authorizing:

Department: MEDICINE
ONCOLOGY

Order Information

Order Date/Time

Release Date/Time

Start Date/Time

End Date/Time

Order Details

+623

+623

+623

Frequency
Once

Duration
1 occurrence

Priority
Routine

Order Class
Normal

Encounter

[View Encounter](#)

Collection Information

Collected: +623

Resulting
Agency:

Order Provider Info

Ordering User

Results In Interface

Office
phone

Pager/beeper

E-mail

Authorizing Provider

[page 3 of 19]
Encounter Date:

+620

PETCT tumor img skull to midhigh

Status: Final result

PACS Images

Show images for PETCT tumor img skull to midhigh

Study Result

Baseline
Scan

SKULL-TO-THIGHS FDG PET/CT SCAN

COMPARISON:

CT abdomen pelvis and CT chest

HISTORY:

+621

+577

male presents for skull-to-thighs FDG PET/CT scan for restaging of cancer of the bowel ducts diagnosed in +0. Patient is status post colon resection, cholecystectomy, and jejunostomy. He has not received chemotherapy or radiation treatment. Patient has a biliary infection and surgical drain inferior to the right lobe of the liver.

The patient's blood glucose level prior to FDG administration was 83 mg/dl.

RADIOPHARMACEUTICAL: 10.8 mCi F-18-FDG injected in the LAC.

TECHNIQUE:

Oral contrast was administered for the CT study; no IV contrast was given. Images were obtained from the base of the skull to the middle thigh.

FINDINGS:

Several stable left supraclavicular lymph nodes demonstrating hypometabolic activity, largest measuring 1 cm with SUV Max 8.1 (image 71).

8 mm superior mediastinal lymph node (Image 81) with SUV Max 5.8. This is decreased in size previously measuring 8 mm.

Hypermetabolic activity fusing to the left hepatic lobe in the region of the pigtail catheter on Image 143 with SUV Max 11.7. There appears to be infiltration of the liver in the area of the tip of the catheter tubing with significantly more activity in this region than would be explained by a simple dilated duct, most consistent with liver involvement. Hypermetabolic activity fusing to a 6.2 cm hypodensity at the liver hilum (Image 148) with SUV max 14.5.

Multiple retroperitoneal mesenteric lymph nodes. These include a stable 8 mm para-aortic node (Image 146) with SUV Max 9.3, a stable 2.1 cm mesenteric lymph node just inferior to the liver (Image 158) with SUV max 12.3, a 6 mm mesenteric lymph node (Image 149) with SUV Max 3.8, stable 1.2 cm paraaortic lymph node (Image 157) with SUV Max 7.8, a stable 1.2 cm and mesenteric lymph node (Image 160) with SUV max 11.7, and a 1.8 cm mesenteric lymph node (Image 172) with SUV Max 12.2.

The remainder of the FDG distribution is physiologic.

Nondiagnostic CT findings:

[page 4 of 19]
Encounter Date

Head and Neck: Supraclavicular lymph nodes as above. The visualized portions of the brain are normal in appearance on CT.

Chest: There is no nodal hypermetabolism in the chest. No hilar or mediastinal adenopathy is evident. Physiologic FDG uptake is noted in the heart. The thyroid gland appears within normal limits. Lung windows demonstrate interval increase in small right pleural effusion. Bilateral atelectasis.

Abdomen and pelvis: Mesenteric and retroperitoneal adenopathy as above. Postsurgical changes of prior cholecystectomy and jejunostomy. Surgical drain inferior to the right lobe of the liver. Hypoattenuation at the liver hilum with hypermetabolic activity as above. The pancreas and spleen are normal. Physiologic FDG excretion is seen in the kidneys and bladder. Multiple bilateral hypodensities in the kidney, likely representing cysts. Largest is in the right kidney measuring 6 cm. 7 mm hyperdensity in the right kidney which may represent hemorrhagic cyst. Significant sigmoid diverticulosis.

Musculoskeletal: Marrow uptake is within normal range. No blastic or lytic lesions are noted on CT. Bone windows demonstrate multilevel degenerative changes of the spine. Prior right hip arthroplasty.

IMPRESSION:

Skull-to-thighs FDG PET/CT scan demonstrating hypermetabolic activity fusing to 2 regions within the liver hilum consistent with a pancreatic head cancer with infiltration into the bile ducts. There appears to be infiltration of the liver in the area of the tip of the catheter tubing with significantly more activity in this region than would be explained by a simple dilated duct, most consistent with liver involvement.

Multiple hypermetabolic mesenteric and retroperitoneal lymph nodes most consistent with metastatic disease. These appear stable in size compared to prior exam.

Several hypermetabolic left supraclavicular lymph nodes and a hypermetabolic left superior mediastinal lymph node concerning for metastatic disease.

The attending radiologist has reviewed all images, agrees with the interpretation, and provided appropriate supervision for this exam.

Imaging

PETCT tumor img skull to midthigh (Order [redacted] Imaging Information)

Result History

PETCT TUM IMG SKULL TO MIDTHIGH ([redacted] Order Result History Report)

Signed by

+623

Signed

Date/Time

Phone

Pager

+623

Prelimed by

Signed

Date

Phone

Pager

+623

Exam Information

Exam

Exam

[page 5 of 19]
Encounter Date:

+620

CT abdomen pelvis w contrast

Status: Final result

PACS Images:

Show images for CT abdomen pelvis w contrast

Study Result

CT ABDOMEN PELVIS W CONTRAST

HISTORY: biliary infection.

COMPARISON +591

TECHNIQUE: Contiguous 4 mm axial CT Images were obtained of the abdomen and pelvis after the administration of Intravenous contrast.

FINDINGS:

Lung bases: Unremarkable.

Musculoskeletal: No acute fracture. Degenerative spine disease.

Right hip prosthesis.

Vessels: Aortic/iliac calcifications.

Lymphatics: No pathologic lymphadenopathy.

Abdomen: Mild intrahepatic biliary dilatation, similar to prior.

Prior cholecystectomy and jejunoostomy. Surgical drain immediately

inferior to the right lobe of the liver. Unchanged regions of

hypodensity within the biliary hilum. 2 subcentimeter

hypodensity immediately inferior to the hepatic bed. 1.3 cm

hypodensity adjacent to the proximal SMA, increased in size from

prior. Multiple periaortic lymph nodes the largest on the left

measuring 2.2 cm, increased in size from prior when it measured

1.7 cm. Prominent lymph nodes adjacent to the pancreas measuring

up to 1.5 cm, similar to prior. Moderate narrowing of the mid

portal vein, similar to prior.

Pancreas: Normal.

Spleen: Unremarkable.

Adrenal glands: Normal right adrenal gland. Mild left adrenal

gland thickening, stable from prior.

GU: Multiple bilateral renal cysts, stable from prior. No stones,

or hydronephrosis.

Urinary bladder: Normal.

GI: Extensive colonic diverticulosis without evidence for

diverticulitis.

IMPRESSION:

Stable intrahepatic biliary dilatation. 2 areas of

hypodensity within the biliary hilum are also unchanged.

Regions of adenopathy within the upper abdomen and

retroperitoneum, some of which appear increased in size as

detailed above.

Stable moderate short segment narrowing of the mid portal vein.

+621

The attending radiologist has reviewed all images, agrees with the interpretation, and provided appropriate supervision for this exam.

[page 6 of 19]
Best response
scan

Procedures Performed:

PET/CT tumor img skull to mid thigh

Exam Time:

+769

Reason for Exam:

RESTAGING

Patient Class:

Outpatient

Diagnosis:

Malignant neoplasm of
intrahepatic bile ducts

SKULL-TO-THIGHS FDG PET/CT SCAN

COMPARISON:

PET/CT [redacted] abdomen and pelvis [redacted]

+669, +623

+623

HISTORY:

Patient is a [redacted] male who presents for skull-to-thighs FDG PET/CT scan for restaging of cholangiocarcinoma. Patient is status post surgical resection of the primary lesion in [redacted] +0. Patient is currently receiving chemotherapy. No history of radiation therapy.

The patient's blood glucose level prior to FDG administration was 80 mg/dl.

RADIOPHARMACEUTICAL: 11 mCi F18-FDG injected in the left port.

TECHNIQUE:

Oral contrast was administered for the CT study; no IV contrast was given. Images were obtained from the base of the skull to the middle thigh.

FINDINGS:

Hypermetsabolic activity is again seen within the left hepatic lobe fusing to the surgical drain near the hepaticojelunostomy site measuring SUV max of 5.2, previously measuring SUV max of 5.9. No corresponding CT abnormality seen.

No appreciable abnormal metabolic activity is seen involving the liver hilum when compared to prior PET/CT.

Previously seen 5 mm retroperitoneal lymph node on the left decreased in size and demonstrates no appreciable metabolic activity on today's exam.

The rest of the FDG distribution is physiologic.

[page 7 of 19]
CT findings:

Head/neck: Limited evaluation of the brain demonstrates no acute abnormality. Bilateral optic globes and retrobulbar structures appear unremarkable. Visualized paranasal sinus disease appear unremarkable. Bilateral parotid and submandibular glands are unremarkable. The nasopharyngeal, oropharyngeal and retropharyngeal soft tissues appear unremarkable on this noncontrasted exam. Thyroid gland appears unremarkable. No enlarged cervical lymphadenopathy.

Chest: Surrounding soft tissues of the chest wall appear unremarkable. No enlarged axillary or subpectoral lymphadenopathy. Subcentimeter mediastinal lymph nodes, none of which are pathologically enlarged. Heart appears normal in size. Coronary artery calcifications. Nonaneurysmal thoracic aorta. Linear scarring or subsegmental atelectasis within the right lower lobe. Linear scarring or atelectasis also seen within the left lower lobe. Trace right pleural effusion similar to prior. No pneumothorax. No pulmonary masses.

Abdomen/Pelvis: Small fat filled umbilical hernia. Spleen, pancreas, bilateral adrenal glands are unremarkable. Stable bilateral renal hypodensities. Well-circumscribed hyperdense focus within the right kidney stable from prior likely hemorrhagic cyst. Extrarenal pelvis on the left. Limited evaluation of the pelvic viscera to streak artifact from right hip prosthesis. Diverticulosis without diverticulitis. Small bowel loops are unremarkable. No evidence for obstruction. No free air or free fluid. Nonaneurysmal abdominal aorta. Postsurgical changes of hepatojejunostomy. IVC seen metastatic implant within the right mid abdomen demonstrates progressive decrease in size with no corresponding metabolic activity seen on today's exam. This measures approximately 7 mm on today's exam and on previous PET/CT from [REDACTED] this measured approximately 1.4 cm.

+669

Bone windows: Right hip arthroplasty. Scoliosis and osseous demineralization.

IMPRESSION:

Skull-to-thighs FDG PET/CT scan demonstrating positive response to therapy with no evidence of disease recurrence.

Hypermetabolic activity again seen within the left hepatic lobe fusing to the drain near the hepatojejunostomy site which is similar to prior exam with no corresponding CT abnormality.

Interval decrease in size of 5 mm retroperitoneal lymph node on the left with no appreciable metabolic activity seen on today's PET/CT.

The attending radiologist has reviewed all images, agrees with the interpretation, and provided appropriate supervision for this

+708

[page 8 of 19]
exam.

Signed By:
Dictated by:

+769

+779

[page 9 of 19]
Procedures Performed:
PETCT tumor lmg skull to mid thigh

DOB: [REDACTED]
Exam Time: [REDACTED]

Sex: Male
Reason for Exam: Malignant neoplasm of intrahepatic bile ducts
Patient Class: Outpatient
Diagnosis: Malignant neoplasm of intrahepatic bile ducts

+861

Result is not yet final

SKULL-TO-THIGHS FDG PET/CT SCAN

COMPARISON:
PET/CT [REDACTED] +779

HISTORY:
[REDACTED] male presents for skull-to-thighs FDG PET/CT scan for restaging of cholangiocarcinoma. Patient is status post surgical resection of the primary lesion in [REDACTED]. Patient is currently receiving chemotherapy. No history of radiation therapy.

+0

The patient's blood glucose level prior to FDG administration was 79 mg/dl.

RADIOPHARMACEUTICAL: 11 mCi F18-FDG injected in the left port.

TECHNIQUE:

Oral contrast was administered for the CT study; no IV contrast was given. Images were obtained from the base of the skull to the middle thigh.

FINDINGS:

Nonspecific hypermetabolic activity within the bilateral parotid glands.

Hypermetabolic activity is again seen within the left hepatic lobe fusing to the surgical drain near the hepaticojejunostomy site measuring SUV max of 5.0, previously measuring SUV max of 5.2. No corresponding CT abnormality seen. This is best seen on images 139 through 145.

The rest of the FDG distribution is physiologic.

CT findings:

Head/neck: Limited evaluation of the brain demonstrates no acute abnormality. Bilateral optic globes and retrobulbar structures appear unremarkable. Visualized paranasal sinus disease appear

+862

[page 10 of 19]
Abdomen/Pelvis: Small fat filled umbilical hernia. Spleen, pancreas, bilateral adrenal glands are unremarkable. Stable bilateral renal hypodensities. Well-circumscribed hyperdense focus within the right kidney stable from prior likely hemorrhagic cyst. Extrarenal pelvis on the left. Hyperdense focus within the left kidney measuring 8 x 8 mm, likely hemorrhagic cyst. Limited evaluation of the pelvic viscera to streak artifact from right hip prosthesis. Diverticulosis without diverticulitis. Small bowel loops are unremarkable. No evidence for obstruction. No free air or free fluid. Nonaneurysmal abdominal aorta. Postsurgical changes of hepatojejunostomy. IVC metastatic implant within the right mid abdomen is not seen on today's exam. This measured approximately 7 mm on or previous PET/CT from [REDACTED] +779. This measured approximately 7 mm.

IMPRESSION:
Skull-to-thighs FDG PET/CT scan demonstrating no evidence of disease progression.

Hypermetabolic activity again seen within the left hepatic lobe fusing to the drain near the hepaticojejunostomy site which is similar to prior exam with no corresponding CT abnormality.

[page 11 of 19]
Most recent
scan

Procedures Performed:
PETCT tumor img skull to midhigh
per protocol

Exam Time:

+1162

Sex:	Patient Class:
Male	Outpatient
Reason for Exam:	Diagnosis:
Malignant neoplasm of Intrahepatic bile ducts	Malignant neoplasm of intrahepatic bile ducts

SKULL-TO-THIGHS FDG PET/CT SCAN

COMPARISON:

PET/CT +954

HISTORY:

male presents for skull-to-thighs FDG PET/CT scan for restaging of cholangiocarcinoma diagnosed in Patient is +0 status post surgical resection of the primary lesion in +0 Status post chemotherapy.

The patient's blood glucose level prior to FDG administration was 88 mg/dl.

RADIOPHARMACEUTICAL: 9.65 mCi F18-FDG injected in the left port.

TECHNIQUE:

Oral contrast was administered for the CT study; no IV contrast was given. Images were obtained from the base of the skull to the middle thigh.

PET FINDINGS:

No regions of abnormal hypermetabolism are visualized on today's exam.

The rest of the FDG distribution is physiologic.

CT findings:

Head/neck: Visualized portion of the brain demonstrate no acute abnormality. Paranasal sinuses are well pneumatized. Thyroid is unremarkable. No cervical lymphadenopathy. Airway is widely patent.

Chest: Surrounding soft tissues of the chest wall appear

+1162

[page 12 of 19]
[REDACTED]

[REDACTED]

unremarkable. Normal heart size. Coronary artery calcifications. No mediastinal adenopathy. Bilateral atelectasis versus scarring which appear stable compared to prior. No pneumothorax, consolidation, or effusion. No pulmonary nodules. Port overlying the left chest with the tip in the SVC.

Abdomen/Pelvis: Postsurgical changes of hepatojejunostomy with no hypermetabolic activity. Small fat filled umbilical hernia. The liver, spleen, bilateral adrenal glands, are normal. Well-circumscribed hyperdense focus within the right kidney stable from prior. Stable bilateral renal hypodensities. Extrarenal pelvis on the left. Nonobstructive bowel gas pattern. Diverticulosis.

Bone windows: Right hip arthroplasty. Scoliosis and osseous demineralization. Degenerative changes of the spine.

IMPRESSION:

No evidence for disease progression.

The attending radiologist has reviewed all images, agrees with the interpretation, and provided appropriate supervision for this exam.

Signed By: [REDACTED]
Dictated by [REDACTED]

+1162

[REDACTED]

+1162

[page 13 of 19]
upload

Imaging Result

Procedures Performed:

PETCT tumor img skull to mid thigh
per protocol

Exam Time:

+1394

Sex:

Male

Patient Class:

Outpatient

Reason for Exam:

Malignant neoplasm

Diagnosis:

Malignant neoplasm of
of intrahepatic bile Intrahepatic bile ducts
duct

SKULL-TO-THIGHS FDG PET/CT SCAN

COMPARISON:

+1162

HISTORY:

male presents for skull-to-thighs FDG PET/CT scan for
restaging of cholangiocarcinoma diagnosed in status post
surgery and chemotherapy.

+0

The patient's blood glucose level prior to FDG administration was
85 mg/dl.

RADIOPHARMACEUTICAL: 10.73 mCi F18-FDG Intravenous
radiopharmaceutical injected in the right antecubital.

TECHNIQUE:

Oral contrast was administered for the CT study; no IV contrast
was given. Images were obtained from the base of the skull to the
middle thigh.

FINDINGS:

No regions of abnormal hypermetabolism are visualized on today's
exam.

The remainder of the FDG distribution is physiologic.

CT findings:

Head/neck: Visualized portions of the brain and calvarium appear
unremarkable. Pneumatization of paranasal sinuses and mastoid air
cells. Major salivary glands and thyroid are unremarkable. No
cervical lymphadenopathy. Airway is widely patent.

Chest: Small pleural effusion in the right lower lobe with
passive atelectasis that is new since prior exam. Bilobar

+1396

[page 14 of 19]
[REDACTED]

atelectasis. No pulmonary nodules identified. Coronary artery calcifications. Heart and pericardium are unremarkable. No hilar, mediastinal, or axillary lymphadenopathy.

Abdomen/Pelvis: Post surgical changes of hepaticojejunostomy without hypermetabolic activity. Otherwise the liver, spleen, stomach, bilateral adrenal glands, and pancreas appear unremarkable. Small fat filled umbilical hernia. Stable bilateral renal cysts. Stable bilateral renal hemorrhagic/proteinaceous cysts. Extrarenal pelvis on the left. Nonobstructive bowel gas pattern. Diverticulosis without diverticulitis. No mesenteric or retroperitoneal lymphadenopathy.

Bone windows: Right hip arthroplasty. Scoliosis. Multilevel degenerative changes throughout the spine. No acute osseous abnormalities.

IMPRESSION:

1. Skull-to-thighs FDG PET/CT scan demonstrating no evidence for disease progression.
2. Small pleural effusion within the right lower lobe that is new since prior exam. Please correlate clinically.

The attending radiologist has reviewed all images, agrees with the interpretation, and provided appropriate supervision for this exam.

[REDACTED]

+1396

[REDACTED]

+1396

[page 15 of 19]
[REDACTED], BL imaging = Day 623

(BL = date of baseline imaging compared to date of first therapy that led to exceptional response.
For this case, no imaging was available at the time of this first therapy)

[page 16 of 19]
BL = Day 623

BL + 2 months = Day 685

BL + 5 months = Day 779

Level 1 case

BL post procedure images do not correlate to true BL clinical state of this patient.

BL = Day 623, C-CT and 18F FDG PET CT (left images)
Hypodense liver lesion by drain, 62 x 36 mm, and with high SUV at PET (arrows)

BL + 2 months = Day 686, C-CT and 18F FDG PET CT (center images)
Liver met, is smaller by CT, 53 x 31 mm, and is less FDG avid. Rapid partial response by 18F FDG PET CT and somewhat smaller by axial CT

BL + 5 months = Day 779, C-CT and 18F FDG PET CT (right images)
Liver met now measures 57 x 36 mm, and remains less FDG avid. Continued partial response by 18F FDG PET CT

[page 17 of 19]
Level 1 case

BL, C-CT and 18F FDG PET CT
Hypodense liver lesion by drain with high SUV at BL PET CT (measured and arrow)

BL post procedure images do not correlate to true BL clinical state of this patient.

Hypodense liver lesion at BL, BL+2m, BL+5m, BL+8m, BL+11m: 62 x 36 mm, 53 x 31 mm, 57 x 35mm, 53 x 23 mm, 45 x 25 mm

Hypodense liver lesion by drain with high BL SUV. Smaller vs BL on these follow up C-CT scan images. PET SUV also normalizes over time. Very rapid partial response by 18F FDG PET CT through BL + 5 months (not shown here), then SUV normalizes by BL + 11 months and is not FDG avid through BL + 25 months

[page 18 of 19]
BL = Day 623

Im: BL + 2 months = Day 685
Se:

BL + 5 months = Day 769

Level 1 case

BL post procedure images do not correlate to true BL clinical state of this patient.

BL = Day 623, C-CT and 18F FDG PET CT (left images)
Abnormal retroperitoneal LNs, 22 x 26 mm, and with high SUV at PET (arrows)

BL + 2 months = Day 686, C-CT and 18F FDG PET CT (center images)
Retroperitoneal LNs at this axial level are smaller by CT, 15 x 13 mm, and are less FDG avid.

Rapid partial response by 18F FDG PET CT

BL + 5 months = Day 767, C-CT and 18F FDG PET CT (right images)
By CT the retroperitoneal LNs at this axial level have normalized. Rapid complete response by FDG PET CT.

[page 19 of 19]
Level 1 case

BL post procedure images do not correlate to true BL clinical state of this patient.

BL = Day 623, C-CT and 18F FDG PET CT (upper images)
Abnormal retroperitoneal LNs, 22 x 26 mm, and with high SUV at PET (arrows)

BL + 2 months = Day 686, 18F FDG PET CT (lower LT and center images)

Retroperitoneal LNs at this axial level are smaller by CT, 15 x 13 mm, and are less FDG avid (arrow).

Rapid partial response by 18F FDG PET CT

BL + 18 months = Day 1162, C-CT (lower RT). By CT the retroperitoneal LNs at this axial level remain normal.

Source: NCI Genomic Data Commons file 07573a67-6b72-41f4-8bed-c8dc4beac749 (ER0399 ER-B0BO Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).